Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4015, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4015-01A (Primary Tumor).

Diagnosis:

Resected colon sample with tumor-free oral, aboral and perirectal resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue (G2, pT3, L1, V0, R0, pN0 0/24).

Source: NCI Genomic Data Commons file 2b4110e1-7424-49b8-b522-0612ece0524d (TCGA-AG-4015.22EE64E1-B7BB-46E2-9677-8A1DE39F2BB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).